Somatic mutation profile of tumor specimen TCGA-BK-A0CC-01A (aliquot TCGA-BK-A0CC-01A-21W-A027-09) from TCGA case TCGA-BK-A0CC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,479 days).
Specimen TCGA-BK-A0CC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d56d70c-8e30-45df-900b-3e066e50888d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A0CC-10A (Blood Derived Normal), aliquot TCGA-BK-A0CC-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/175c66b1-dfab-4834-a728-35ff1048ab0a

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 77/120 reads (64%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ATP9B | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs952837369, COSV56947200; called by muse, mutect2, varscan2
- CARMIL1 | c.3668G>A p.R1223H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs775578827, COSV61515400; called by muse, mutect2, varscan2
- CDH7 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 136/234 reads (58%) | catalogued as rs766062933, COSV59885424; called by muse, mutect2, varscan2
- CR1L | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54325468; called by muse, mutect2
- DHDDS | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1383907275, COSV52575755; called by muse, mutect2, varscan2
- DLC1 | c.4529A>C p.K1510T (on ENST00000276297 / NM_001348081.2; = p.K1073T on NM_006094.5) | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV52301520; called by muse, mutect2, varscan2
- DNAH11 | c.3529C>G p.L1177V | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.903); catalogued as rs750181929, COSV60953781; called by muse, mutect2, varscan2
- EPHA7 | c.1224C>G p.H408Q | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs145928664, COSV65182043, COSV65183842, COSV65190177; called by muse, mutect2, varscan2
- FAT1 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 163/255 reads (64%) | catalogued as COSV71672105; called by muse, mutect2, varscan2
- FAT4 | c.11906-1G>C p.X3969_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as COSV58682550; called by muse, mutect2, varscan2
- IL3RA | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV58431048; called by muse, mutect2, varscan2
- MAIP1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1048972908, COSV54460546; called by muse, mutect2
- MOCS1 | c.922T>C p.S308P | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57935899; called by muse, mutect2
- NSUN4 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as rs141622103; called by muse, mutect2, varscan2
- OR2T33 | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 79/617 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58815191; called by muse, mutect2, varscan2
- OR4F15 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 363/956 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV59968914; called by muse, mutect2, varscan2
- PCDH15 | c.3241G>C p.G1081R | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV100213884, COSV57301824; called by muse, mutect2, varscan2
- PHLPP2 | c.3617G>A p.R1206Q | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as rs1400230640, COSV62423299; called by muse, mutect2, varscan2
- PIK3C2B | c.4582G>A p.G1528S | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs556813529, COSV65811100; called by muse, mutect2
- SETBP1 | c.4202G>T p.R1401L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs775975116, COSV56320530; called by muse, mutect2, varscan2
- SORCS3 | c.2940G>T p.Q980H | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63794786, COSV63796067; called by muse, mutect2, varscan2
- SUGP2 | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58258071; called by muse, mutect2
- TAX1BP1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367927936; called by muse, mutect2, varscan2
- TSPYL1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.398); catalogued as COSV63994045; called by muse, mutect2, varscan2
- UBL4A | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs782283486, COSV54836217; called by muse, mutect2, varscan2
- ZC3H7B | c.494_503del p.L165Pfs*36 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV60961730; called by mutect2, pindel
- ZNF449 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 92/136 reads (68%) | catalogued as COSV59346904; called by muse, mutect2, varscan2
- ZRANB1 | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 390/872 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV62842306; called by muse, mutect2, varscan2
- AMOTL2 | c.1672_1674del p.Q558del | In Frame Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, pindel, varscan2
- KLHL41 | c.114del p.A39Qfs*11 | Frame Shift Del (DEL) | VAF 57/207 reads (28%) | called by mutect2, pindel, varscan2
- ATP5F1B | c.318C>T p.S106= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV56260852; called by muse, mutect2, varscan2
- ATP6V0D2 | c.804G>A p.A268= | Silent (SNP) | VAF 284/484 reads (59%) | catalogued as rs749834977, COSV53414562; called by muse, mutect2, varscan2
- GPR31 | c.849C>T p.C283= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV64761401; called by muse, mutect2, varscan2
- MMRN1 | c.3178A>C p.R1060= | Silent (SNP) | VAF 48/174 reads (28%) | catalogued as COSV53336981; called by muse, mutect2, varscan2
- NKIRAS1 | c.483C>T p.F161= | Silent (SNP) | VAF 102/449 reads (23%) | catalogued as COSV60667504; called by muse, mutect2, varscan2
- OCA2 | c.150C>T p.S50= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV62344526; called by muse, mutect2, varscan2
- SLC22A2 | c.1182C>A p.I394= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV65266167, COSV65266823; called by muse, mutect2, varscan2
- SMG5 | c.2523G>A p.E841= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV52745070, COSV99431537; called by muse, mutect2, varscan2
- TRAM1L1 | c.288A>C p.T96= | Silent (SNP) | VAF 4/93 reads (4%) | catalogued as COSV60291803; called by muse, mutect2
- VCL | c.3045C>T p.L1015= (on ENST00000211998 / NM_014000.3; = p.L947= on NM_003373.4) | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV53007756; called by muse, mutect2, varscan2
- ZNF292 | c.4728A>G p.L1576= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as COSV60538923; called by muse, mutect2, varscan2
